Somatic mutation profile of tumor specimen 0DDROH from CCDI case PBBPFA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 7.3 years (2,650 days).
Specimen 0DDROH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bde3d1a-f910-468f-b12b-226d83331ac8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDROI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56d8b594-36c6-41b9-a6f3-00d56ef2e26a

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA1671 | c.4632G>C p.Q1544H | Missense Mutation (SNP) | VAF 303/642 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.568); catalogued as COSV64449096; called by muse, mutect2, varscan2
- LDB1 | c.1057G>A p.E353K (on ENST00000425280 / NM_001321612.2; = p.E319K on NM_003893.5) | Missense Mutation (SNP) | VAF 286/609 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63289589, COSV63289595; called by muse, mutect2, varscan2
- LRRC19 | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 164/941 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs1441434523; called by muse, mutect2, varscan2
- MTA1 | c.1939C>G p.R647G | Missense Mutation (SNP) | VAF 258/567 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as COSV58760492; called by muse, mutect2, varscan2
- NOP53 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 49/596 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1016797477; called by muse, mutect2
- CCDC158 | c.1641G>C p.Q547H | Missense Mutation (SNP) | VAF 229/934 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CPNE8 | c.591C>A p.H197Q | Missense Mutation (SNP) | VAF 71/677 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- KCNMA1 | c.641C>A p.T214K | Missense Mutation (SNP) | VAF 117/524 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- OR4D1 | c.43T>A p.L15I | Missense Mutation (SNP) | VAF 77/1656 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2
- TMTC1 | c.2019C>G p.Y673* (on ENST00000539277 / NM_001193451.2; = p.Y565* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 119/471 reads (25%) | called by muse, mutect2, varscan2
- URI1 | c.361A>G p.K121E | Missense Mutation (SNP) | VAF 132/473 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- ADNP2 | c.450C>T p.S150= | Silent (SNP) | VAF 228/507 reads (45%) | catalogued as rs770107576; called by muse, mutect2, varscan2
- APOB | c.10509G>A p.S3503= | Silent (SNP) | VAF 83/799 reads (10%) | catalogued as rs769351301, COSV51938330; ClinVar: likely benign; called by muse, mutect2, varscan2
- EMB | c.24G>A p.L8= | Silent (SNP) | VAF 150/553 reads (27%) | catalogued as COSV57482929; called by muse, mutect2, varscan2
- PIGC | c.63A>C p.R21= | Silent (SNP) | VAF 28/954 reads (3%) | called by muse, mutect2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 6/90 reads (7%) | catalogued as rs1262556378; called by muse, mutect2
- EVPL | c.1439+46G>T | Intron (SNP) | VAF 141/399 reads (35%) | called by muse, mutect2, varscan2
- LINC01811 | n.327C>A | RNA (SNP) | VAF 62/340 reads (18%) | called by muse, mutect2
